TARGET case TARGET-30-PAMCXF — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e7aad601-c654-5c99-a434-3a93d7744934

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 2 years; Vital status: Dead; Days to death: 718 days (2.0 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C80.0; Classification of tumor: primary; Age at diagnosis: 2.1 years (765 days); Year of diagnosis: 2003; Days to last follow up: 718 days (2.0 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: High.
   Treatment given: Protocol identifier: ANBL00B1.
   Treatment given: Protocol identifier: A3973.

Follow-up (2 entries)
- Days to follow up: 376 days (1.0 years); Days to first event: 376 days (1.0 years); First event: Progression.
- Days to follow up: 718 days (2.0 years); Year of follow up: 2005.

Molecular and laboratory tests
- MYCN amplification: Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PAMCXF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAMCXF-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 718
- Protocol: ANBL00B1, A3973
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.17
- Histology: Unfavorable
- ICDO Description: Right adrenal (this was added from text description)
- Site of Relapse: Primary Site
